Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2Q6, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2Q6-01A (Primary Tumor).

[page 1 of 4]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

year old metastatic papillary thyroid carcinoma.

Specimens Submitted:

- 1: Right neck skin scar
- 2: Right neck level two lymph node
- 3: Right neck level three lymph node
- 4: Right neck level four and five-B lymph node
- 5: Total thyroidectomy and right level 6 lymph nodes

DIAGNOSIS:

1. Skin, right neck; excision:
- Benign skin with scar with giant cell reaction
2. Right neck level two lymph node:
Lymph Node Dissection:
Metastatic papillary carcinoma
Number of lymph nodes examined: 12
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 1cm.
Size of the largest metastatic focus : 0.6 cm.
Extranodal extension is identified
3. Right neck level three lymph node:
Lymph Node Dissection:
Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 12
Number of lymph nodes with metastatic disease: 4
Size of the largest lymph node involved by tumor: 1.1cm.
Size of the largest metastatic focus : 0.9 cm.
Extranodal extension is not identified
4. Right neck level four and five-B lymph node:
Lymph Node Dissection:
Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 5
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.3cm.
Size of the largest metastatic focus : 0.05 cm.
Extranodal extension is not identified

1CD-0-3
carcinoma, papillary, thyroid 8360/3
Site thyroid, NOS 073.9
fw
8/31/11

[page 2 of 4]
5. Total thyroidectomy and right level 6 lymph nodes:

Tumor Type:

Multiple foci of papillary carcinoma: two classical type and six papillary microcarcinomas

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Left lobe

Right lobe

Isthmus

The two largest tumor foci are located in the right lobe

Tumor Size:

Tumor foci range from 0.1 cm to 1.1 cm in greatest dimension

Tumor Encapsulation:

None identified

For the classical type carcinomas

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades fibroadipose tissue

Surgical Margins:

Free of tumor

Tumor is noted very close (< one high power field) from the inked margin

Tumor Multicentricity:

gross and microscopic foci present

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Mild

Parathyroid Glands:

Identified

One unremarkable parathyroid fragment is noted adjacent to the left lobe

Lymph Nodes:

Number of nodes examined: 16

The largest metastatic node is 1.1 cm

Perinodal (extracapsular) extension identified

Fifteen of sixteen lymph nodes show metastatic papillary carcinoma (15/16)

Comment: Benign large vessel is noted.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 3 of 4]
Gross Description:

1). The specimen is received fresh, labeled "Right neck skin scar" and consists of a 3.5 x 1 x 0.7 cm ellipse of tan skin with a well healed linear scar. Representative sections are submitted.

Summary of sections:

U - undesignated

2). The specimen is received fresh, labeled "Right neck level two lymph node" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 1.5 cm in greatest dimension. All identified lymph nodes are submitted to include TPS from grossly involved nodes.

Summary of sections:

LN - lymph nodes (two TPS-ed nodes in 1)

BLN - bisected lymph nodes

3). The specimen is received fresh, labeled "Right neck level three lymph node" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 1.4 cm in greatest dimension. All identified lymph nodes are submitted to include TPS from grossly involved node.

Summary of sections:

LN - lymph nodes (TPS-ed node in 1)

4). The specimen is received fresh, labeled "Right neck levels four and five B lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 0.7 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

BLN - bisected lymph nodes

5). The specimen is received fresh, labeled "total thyroidectomy and right level 6 lymph nodes (neck) short stitch marks right superior pole long stitch marks left lower pole" and consists of a thyroid with attached portion of fatty soft tissue; a separate portion of fibroadipose tissue is also present (aggregate size of 5 x 1.5 x 0.7 cm for both fragments). The thyroid weighs 11.5 g. The right lobe measures 3.9 x 1.8 x 1.7 cm, the left lobe measures 3.5 x 2.2 x 1.4 cm and the isthmus measures 2 x 0.7 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals two nodules in the right lobe: N1 - 1.1 x 0.8 x 0.8 cm white firm solid poorly circumscribed, in the upper pole, and N2 - 1 x 0.7 x 0.7 cm white firm solid poorly circumscribed in the lower pole. Sections through the left lobe reveal a 0.3 cm firm white nodule in the mid pole (N3). The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen (N1 and 2) are submitted for TPS. The remaining thyroid is entirely submitted. Multiple lymph nodes are dissected ranging from 0.2 to 1.1 cm, four of which are grossly involved by tumor - portion of these 4 nodes is given to TPS; the remaining nodes are entirely submitted. Also 4.5 cm long segment of a vessel is present which is grossly unremarkable.

Summary of sections:

N 1 - nodule 1

N2 - nodule 2

N3 - nodule 3

RL - right lobe

[page 4 of 4]
LL - left lobe
IS - isthmus
LN - lymph nodes (4 TPS-ed nodes in 14)
V - vessel

Summary of Sections:

Part 1: Right neck skin scar

Block	Sect. Site	PCs
1	U	1

Part 2: Right neck level two lymph node

Block	Sect. Site	PCs
1	BLN	6
2	LN	2

Part 3: Right neck level three lymph node

Block	Sect. Site	PCs
2	LN	5

Part 4: Right neck level four and five-B lymph node

Block	Sect. Site	PCs
1	BLN	2
1	LN	3

Part 5: Total thyroidectomy and right level 6 lymph nodes

Block	Sect. Site	PCs
1	IS	2
4	LL	4
2	LN	9
2	N1	2
2	N2	2
1	N3	2
3	RL	3
1	V	1

Source: NCI Genomic Data Commons file 0c6e35e1-4f6f-4a76-b994-5933d2b2b026 (TCGA-DJ-A2Q6.CCF825BD-7410-4ED2-B0E2-8B17BB5C5BBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).